Gene-level copy-number profile of tumor specimen C3N-01409-04 from CPTAC case C3N-01409, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 60.2 years (22,005 days).
Specimen C3N-01409-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file db5c156d-06c7-4cdf-8b81-fc1f98819119.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01409-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/44b25f2b-b9ff-4fd3-ad2c-7d31af39c29f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 8,602; copy number 2: 38,460; copy number 3: 10,796; copy number 4: 439; copy number 5: 88.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,128,103, 14 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr22:18,605,355–18,615,900, 4 genes: AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 88 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:44,062,727–45,542,182, 47 genes, copy number 5 (within-gene range 3–5): PGAM2, AC017116.1, POLM, MIR6838, AEBP1, MIR4649, POLD2, RNA5SP230, MYL7, GCK, YKT6, CAMK2B, AC004453.2, NUDCD3, AC004453.1, RNU6-1097P, AC004938.1, NPC1L1, DDX56, TMED4, AC011894.1, OGDH, ZMIZ2, AC013436.1, PPIA, H2AZ2, LINC01952, PURB, MIR4657, AC004854.2, AC004854.1, AC004847.1, MYO1G, SNHG15, SNORA9, CCM2, NACAD, TBRG4, SNORA5A, SNORA5C, SNORA5B, RAMP3, AC073968.2, AC073968.1, ELK1P1, AC073325.1, AC073325.2.
- chr16:3,725,054–4,767,624, 41 genes, copy number 5: CREBBP, AC007151.1, LINC02861, ADCY9, AC005736.1, AC009171.1, AC009171.2, SRL, LINC01569, TFAP4, GLIS2, GLIS2-AS1, PAM16, AC012676.1, CORO7-PAM16, AC012676.5, CORO7, VASN, DNAJA3, AC012676.3, AC012676.4, AC012676.2, NMRAL1, HMOX2, CDIP1, AC023830.3, C16orf96, AC023830.2, SUB1P3, UBALD1, MGRN1, RN7SL850P, AC023830.1, Metazoa_SRP, MIR6769A, NUDT16L1, ANKS3, AC020663.1, C16orf71, ZNF500, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 8,602. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
